Somatic mutation profile of tumor specimen TCGA-IN-AB1V-01A (aliquot TCGA-IN-AB1V-01A-21D-A410-08) from TCGA case TCGA-IN-AB1V, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 63.1 years (23,030 days).
Specimen TCGA-IN-AB1V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 275e54b5-663a-4960-80ca-ba185e559ad7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-AB1V-10A (Blood Derived Normal), aliquot TCGA-IN-AB1V-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/966814eb-c5bd-4759-bc27-e565fb349e0f

The open-access MAF lists 57 somatic variants for this specimen: 38 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 33, Silent 19, In Frame Del 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA3 | c.1637G>A p.R546K | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100069147; called by muse, mutect2, varscan2
- ATP6V0D2 | c.892-1G>A p.X298_splice | Splice Site (SNP) | VAF 28/114 reads (25%) | catalogued as COSV99572075; called by muse, varscan2
- DNAJB1 | c.469C>G p.R157G | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99584268; called by muse, mutect2, varscan2
- FXR2 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs374495529; called by muse, mutect2, varscan2
- GRM7 | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs748112708, COSV100738755; called by muse, varscan2
- H1-5 | c.67_69del p.K23del | In Frame Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs1463409355; called by pindel, varscan2
- INHBB | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs770068466, COSV54677648; called by muse, mutect2, varscan2
- INSIG1 | c.537T>A p.A179= | Splice Region (SNP) | VAF 27/159 reads (17%) | catalogued as COSV60921245; called by muse, mutect2, varscan2
- ITGB7 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs747008975, COSV57238064; called by muse, mutect2, varscan2
- KIAA1549 | c.4201C>G p.P1401A | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.265); catalogued as rs267601311, COSV54320349, COSV99652074; called by muse, mutect2, varscan2
- KIF2B | c.1672G>A p.G558R | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.039); catalogued as COSV52130762, COSV52136291; called by muse, mutect2, varscan2
- KRT14 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.36); catalogued as rs61540016, CM001204, COSV51420112; called by muse, mutect2, varscan2
- LMO7 | c.3176-1G>A p.X1059_splice (on ENST00000357063; = p.X740_splice on NM_005358.5) | Splice Site (SNP) | VAF 8/96 reads (8%) | catalogued as COSV100413872; called by muse, mutect2
- LTF | c.308C>A p.T103N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.282); catalogued as COSV99211875; called by muse, mutect2, varscan2
- MUC5AC | c.16633G>A p.G5545S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.949); catalogued as rs763107684, COSV100611603; called by muse, mutect2
- MUC6 | c.67T>A p.S23T | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.239); catalogued as COSV101424802; called by muse, mutect2
- OR4K13 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs149397731; called by muse, mutect2, varscan2
- OR8H3 | c.179T>A p.M60K | Missense Mutation (SNP) | VAF 49/370 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100539154; called by muse, mutect2, varscan2
- PAPPA | c.3290C>T p.A1097V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.268); catalogued as COSV100075378; called by muse, mutect2, varscan2
- PCDHB4 | c.34C>A p.Q12K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV99078122; called by muse, mutect2, varscan2
- PLK3 | c.921G>T p.Q307H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV100221301; called by muse, mutect2, varscan2
- POLN | c.1386G>T p.K462N | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV101242803; called by muse, mutect2, varscan2
- POM121L12 | c.422T>A p.I141N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101374986, COSV101375002; called by muse, mutect2, varscan2
- PTCH2 | c.906G>C p.M302I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100942283; called by muse, mutect2, varscan2
- PTPRB | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0.027); catalogued as COSV99719028; called by muse, varscan2
- TJP1 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs1304157065, COSV100632885; called by muse, mutect2, varscan2
- TMC1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.007); catalogued as rs140437301; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMC2 | c.2573A>G p.N858S | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62651270, COSV62658033; called by muse, mutect2, varscan2
- TNFRSF21 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1486560560, COSV99730270; called by muse, mutect2, varscan2
- TRPA1 | c.1066A>C p.N356H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV100085237; called by muse, mutect2, varscan2
- TSHR | c.2018C>A p.A673D | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99992892; called by muse, mutect2, varscan2
- TXNDC16 | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99909691; called by muse, mutect2
- USP28 | c.2250T>G p.I750M | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV99136854; called by muse, mutect2, varscan2
- WNT7A | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1426757027, COSV53198801; called by muse, mutect2
- WNT9B | c.520A>G p.S174G | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV99255395; called by muse, mutect2
- XRRA1 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100370136; called by muse, mutect2, varscan2
- ZFP36L2 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs766861473, COSV99144254; called by muse, mutect2
- MUC6 | c.6795_6797del p.S2266del | In Frame Del (DEL) | VAF 29/177 reads (16%) | called by pindel, varscan2
- ANAPC1 | c.4311T>C p.N1437= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- CRYGA | c.165G>A p.Q55= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100378671; called by muse, mutect2, varscan2
- FLG | c.4527A>G p.V1509= | Silent (SNP) | VAF 13/392 reads (3%) | catalogued as COSV64238184; called by muse, mutect2
- GAB2 | c.561C>T p.S187= (on ENST00000361507 / NM_080491.3; = p.S149= on NM_012296.3) | Silent (SNP) | VAF 36/171 reads (21%) | catalogued as rs1314327035, COSV100416871; called by muse, mutect2, varscan2
- GABRA4 | c.54C>T p.F18= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as rs1191157565, COSV99974715; called by muse, mutect2, varscan2
- GABRB1 | c.832C>T p.L278= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs1216107953, COSV99780392, COSV99783557; called by muse, mutect2, varscan2
- GGCX | c.2130T>A p.R710= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- IGHV3-49 | c.190C>T p.L64= | Silent (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2
- INTS4 | c.2298C>A p.I766= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV100490139; called by muse, mutect2, varscan2
- KLHL23 | c.1503C>T p.C501= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as rs781533649, COSV99776125; called by muse, mutect2, varscan2
- MAGI2 | c.1071C>T p.I357= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs754843992, COSV62637309; called by muse, mutect2, varscan2
- OCIAD1 | c.264T>C p.F88= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV99971290; called by muse, varscan2
- OR2T33 | c.117C>A p.G39= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV100532310, COSV58817692; called by muse, mutect2, varscan2
- SLC25A45 | c.531G>A p.T177= | Silent (SNP) | VAF 23/144 reads (16%) | catalogued as rs770586479, COSV99587395; called by muse, mutect2, varscan2
- SLC6A3 | c.1581C>T p.V527= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV54369427, COSV99548892; called by muse, mutect2, varscan2
- SMG1 | c.6507C>T p.F2169= | Silent (SNP) | VAF 27/220 reads (12%) | catalogued as COSV101246871; called by muse, mutect2, varscan2
- SPRED1 | c.1005C>T p.C335= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as rs768937237, COSV100136067; ClinVar: likely benign; called by muse, mutect2, varscan2
- TXLNB | c.357A>G p.P119= | Silent (SNP) | VAF 22/268 reads (8%) | catalogued as COSV100625187; called by muse, mutect2
- TXNDC16 | c.1443A>T p.G481= | Silent (SNP) | VAF 27/138 reads (20%) | catalogued as COSV99909689; called by muse, mutect2
